Somatic mutation profile of tumor specimen TCGA-28-2499-01A (aliquot TCGA-28-2499-01A-01D-1494-08) from TCGA case TCGA-28-2499, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 59.8 years (21,838 days).
Specimen TCGA-28-2499-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1969baae-04bb-4ef2-ac22-49cbadf632a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-28-2499-10A (Blood Derived Normal), aliquot TCGA-28-2499-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3581ef2-1b14-4694-8da7-3f9243fb01af

The open-access MAF lists 29 somatic variants for this specimen: 26 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 23, Silent 3, Splice Site 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AL669918.1 | c.2111G>A p.S704N | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.506); catalogued as COSV71270931; called by muse, mutect2, varscan2
- AXIN1 | c.2336C>T p.P779L | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs1288498476, COSV51985846; called by muse, mutect2, varscan2
- CDH9 | c.1031C>A p.T344N | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.583); catalogued as COSV50267140, COSV50280435; called by muse, mutect2, varscan2
- CNMD | c.265T>C p.S89P | Missense Mutation (SNP) | VAF 131/165 reads (79%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.694); catalogued as COSV65032784; called by muse, mutect2, varscan2
- CTSS | c.308G>A p.R103K | Missense Mutation (SNP) | VAF 184/407 reads (45%) | SIFT tolerated (0.42); PolyPhen benign (0.034); catalogued as COSV64566149; called by muse, mutect2, varscan2
- DDX56 | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 38/155 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.143); catalogued as rs1338584124, COSV51835992; called by muse, mutect2, varscan2
- FAM83B | c.2806C>T p.R936C | Missense Mutation (SNP) | VAF 77/207 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1410767041, COSV60921083; called by muse, mutect2, varscan2
- FRAS1 | c.8468G>A p.R2823H | Missense Mutation (SNP) | VAF 241/572 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs748866013, COSV53602689; called by muse, mutect2, varscan2
- GML | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 80/176 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.674); catalogued as rs181298814, COSV55277074; called by muse, mutect2, varscan2
- GPS1 | c.97G>A p.V33I | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs146475501, COSV57648455; called by muse, mutect2, varscan2
- LAMB4 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 93/345 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs756743601, COSV52717034; called by muse, mutect2, varscan2
- LAMTOR2 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV64145184; called by muse, mutect2
- LGI3 | c.1321C>T p.R441C | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs763244062, COSV60443196; called by muse, mutect2, varscan2
- MAGI2 | c.3419C>A p.P1140H | Missense Mutation (SNP) | VAF 41/335 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as COSV62645098; called by mutect2, varscan2
- NFXL1 | c.1916+1G>A p.X639_splice | Splice Site (SNP) | VAF 9/122 reads (7%) | catalogued as COSV61198552; called by muse, mutect2
- PABPC1L | c.1133T>A p.L378* | Nonsense Mutation (SNP) | VAF 201/428 reads (47%) | catalogued as COSV53839910; called by muse, mutect2, varscan2
- PHRF1 | c.1937C>T p.A646V (on ENST00000264555 / NM_001286581.2; = p.A645V on NM_020901.4) | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.077); catalogued as rs756569593, COSV52753980; called by muse, mutect2, varscan2
- PKD1L2 | c.1957C>T p.L653F | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as COSV55160274; called by muse, mutect2, varscan2
- PTCD2 | c.154G>A p.V52M | Missense Mutation (SNP) | VAF 72/198 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.607); catalogued as rs1373425376, COSV54650031; called by muse, mutect2, varscan2
- SLC13A2 | c.1379C>T p.A460V | Missense Mutation (SNP) | VAF 64/144 reads (44%) | SIFT tolerated (0.58); PolyPhen benign (0.03); catalogued as rs1555604511, COSV58994253; called by muse, varscan2
- SPP2 | c.278G>A p.R93K | Missense Mutation (SNP) | VAF 80/186 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0.043); catalogued as COSV51445105; called by muse, mutect2, varscan2
- TEKT5 | c.448T>C p.F150L | Missense Mutation (SNP) | VAF 103/250 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV51587815; called by muse, mutect2, varscan2
- TFDP1 | c.250C>A p.P84T | Missense Mutation (SNP) | VAF 34/48 reads (71%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV64739873; called by muse, mutect2, varscan2
- TRPC6 | c.2678G>T p.S893I | Missense Mutation (SNP) | VAF 126/217 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60252693; called by muse, mutect2, varscan2
- WDR72 | c.2029G>A p.V677I | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs747991720, COSV64741881; called by muse, mutect2, varscan2
- ZNF337 | c.2051del p.P684Lfs*49 | Frame Shift Del (DEL) | VAF 130/333 reads (39%) | called by mutect2, pindel, varscan2
- CALR | c.402C>T p.P134= | Silent (SNP) | VAF 58/129 reads (45%) | catalogued as rs371325705; called by muse, mutect2, varscan2
- FAT3 | c.5607C>T p.V1869= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV53096770; called by mutect2, varscan2
- TLN2 | c.5355C>T p.G1785= | Silent (SNP) | VAF 52/117 reads (44%) | catalogued as rs1370162571, COSV60888126; called by muse, mutect2, varscan2
